Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BU, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BU-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:
Right thigh soft tissue mass.

Specimens Submitted:

- 1: SP: Biopsy right thigh
- 2: SP: Cloquet node right groin
- 3: SP: Proximal margin of right psoas muscle
- 4: SP: Deep margin
- 5: SP: Medial deep margin
- 6: SP: Margin of profunda
- 7: SP: Right thigh mass

DIAGNOSIS:

1. SOFT TISSUE, RIGHT THIGH; BIOPSY:
- POSITIVE FOR HIGH GRADE SARCOMA (SEE PART 7).
2. LYMPH NODE, RIGHT GROIN CLOQUET; EXCISION:
- ONE BENIGN LYMPH NODE.
3. SOFT TISSUE, RIGHT PSOAS MUSCLE, PROXIMAL MARGIN; EXCISION:
- SKELETAL MUSCLE, NO TUMOR SEEN.
4. SOFT TISSUE, RIGHT THIGH, DEEP MARGIN; EXCISION:
- FIBROMUSCULAR TISSUE, NO TUMOR SEEN.
5. SOFT TISSUE, RIGHT THIGH, MEDIAL DEEP MARGIN; EXCISION:
- FIBROMUSCULAR TISSUE, NO TUMOR SEEN.
6. SOFT TISSUE, MARGIN OF PROFUNDA; BIOPSY:
- FIBROMUSCULAR TISSUE, NO TUMOR SEEN.
7. SOFT TISSUE, RIGHT THIGH MASS; RESECTION:
- UNDIFFERENTIATED HIGH GRADE PLEOMORPHIC AND SPINDLE CELL SARCOMA (MALIGNANT FIBROUS HISTIOCYTOMA) INVOLVING FIBROADIPOSE TISSUE AND SKELETAL MUSCLE.
- TUMOR MEASURES 12.4 CM GREATEST DIMENSION AND SHOWS ABOUT 30% NECROSIS.
- TUMOR INVOLVES PROXIMAL AND DEEP INKED SPECIMEN MARGINS AND COMES WITHIN 0.17 CM OF LATERAL AND 0.3 CM OF MEDIAL MARGIN.

** Continued on next page **

ICD-O-3
Histocytoma, malignant
fibrous pleomorphic 8830/3
Site @ Thigh NOS C49.2
JW 11/22/13

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Page 2 of 5

- VASCULAR INVASION IS PRESENT
- A LARGE PERIPHERAL NERVE IS FREE OF TUMOR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh labeled "biopsy right thigh" and consists of gray-tan fragments of soft tissue measuring 1.2 x 0.3 x 0.3 cm in aggregate. The specimen is entirely submitted for frozen section.

Summary of sections
FSC-frozen section control

2) The specimen is received fresh labeled "cloquet node right groin" and consists of a pink-tan soft tissue fragment (apparent lymph node) measuring 2.2 x 2.2 x 0.7 cm. A portion of the specimen is submitted for frozen section and the frozen tissue is submitted for histologic examination. The remaining tissue is entirely submitted.

Summary of sections
FSC-frozen section control
U-undesignated

3) The specimen is received fresh for frozen section, labeled "Proximal margin of right psoas muscle" and consists of a flattened to irregularly shaped unoriented piece of red-tan somewhat friable skeletal muscle measuring 5.7 x 4.5 x 0.5 cm. The specimen has been previously incised and the external surface is inked black. The specimen is serially sectioned to reveal homogenous red-tan tissue, with no discrete abnormalities identified. A representative section is submitted for frozen section, the remaining tissue is serially sectioned and submitted entirely.

Summary of sections:
FSC -- frozen section control
SS serial sections remaining tissue

4) The specimen is received fresh for frozen section, labeled "Deep margin" and consists of an irregularly shaped unoriented fragment of

** Continued on next page **

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

----- Page 3 of 5
pink-tan soft tissue measuring 2.0 x 0.4 x 0.2 cm. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

5) The specimen is received fresh for frozen section, labeled "Medial deep margin" and consists of a fragment of brown-tan soft tissue measuring 1.0 x 0.7 x 0.3 cm. Entirely submitted for frozen section.

Summary of sections:

FSC at frozen section control

6) The specimen is received fresh for frozen section, labeled "Margin of profunda" and consists of a fragment of soft tissue measuring 0.6 x 0.3 x 0.2 cm. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

7) The specimen is received fresh labeled "Right thigh mass, right stitch deep margin, black stitch distal margin, green stitch proximal psoas tendon". It consists of a segment of skeletal muscle and attached yellow-tan fatty tissue measuring 17 x 15 x 7.5 cm. The anterior skeletal muscle measures 14 x 7.5 x 1.7 cm. There are three stitches attached to the specimen. The white stitch marks the deep margin, the black stitch marks the distal margin, and the green stitch marks the proximal psoas tendon. The specimen is inked as follows: deep margin black, proximal margin blue, distal margin green, superficial and medial margin red, lateral margin yellow. The specimen is bivalved to reveal a well circumscribed, faintly lobulated fleshy hemorrhagic white-tan tumor measuring 12.4 x 8.4 x 7.9 cm. The tumor is located 2 cm from the distal soft tissue margin, 0.4 cm from the superficial soft tissue margin, 0.3 cm from medial soft tissue margin, and abuts the lateral, deep, and proximal soft tissue margins. The tumor is located 6 cm from the psoas tendon margin, which is shaved and submitted entirely. Representative perpendicular sections of the remaining soft tissue margins are submitted. Representative sections are submitted. A sample of the tumor is given to TPS. The specimen has been photographed.

Summary of sections:

LM-lateral margin
MM-medial margin
DM-deep margin
AM-superficial margin
SM-proximal soft tissue margin
IM-distal margin
PTM-psoas tendon margin
T-tumor

** Continued on next page **

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

Page 4 of 5

Summary of Sections:

Part 1: SP: Biopsy right thigh

Block	Sect.	Site	PCs
1	fsc		0

Part 2: SP: Cloquet node right groin

Block	Sect.	Site	PCs
1	fsc		0
3	u		0

Part 3: SP: Proximal margin of right psoas muscle

Block	Sect.	Site	PCs
1	fsc		1
17	ss		17

Part 4: SP: Deep margin

Block	Sect.	Site	PCs
1	fsc		1

Part 5: SP: Medial deep margin

Block	Sect.	Site	PCs
1	fsc		1

Part 6: SP: Margin of profunda

Block	Sect.	Site	PCs
1	fsc		1

Part 7: SP: Right thigh mass

Block	Sect.	Site	PCs
2	AM		2
2	DM		2
2	IM		2
3	LM		3
2	MM		2
1	PTM		1
2	SM		2
6	T		6

** Continued on next page **

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

----- Page 5 of 5

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: MALIGNANT NEOPLASM DEFER TO PERMANENTS; FAVOR SARCOMA.
PERMANENT DIAGNOSIS: SEE FINAL DIAGNOSIS (SARCOMA).
- 2) FROZEN SECTION DIAGNOSIS: NEGATIVE FOR TUMOR.
PERMANENT DIAGNOSIS: SAME.
- 3) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 4) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 5) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 6) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.

** End of Report **

Discrepancy		☒
HIKAA Discrepancy		☒
Prior Discrepancy History		☒

Source: NCI Genomic Data Commons file 11693e62-4a15-4aa0-929b-c8190c1c89e2 (TCGA-DX-A8BU.FF796E4E-DD5F-4D72-B4BE-8D41F5F7DE8F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).